Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4887, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4887-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) RIGHT KIDNEY:

RENAL CELL CARCINOMA (4.0 CM MAXIMUM DIMENSION), CONVENTIONAL TYPE
(40% CLEAR CELLS,
60% EOSINOPHILIC CELLS), FUHRMAN NUCLEAR GRADE 3, INVASIVE
INTO RENAL VEIN.
(SEE COMMENT).

Margins of resection free of tumor.

(B) LEFT ADRENAL GLAND:

METASTATIC CONVENTIONAL RENAL CELL CARCINOMA IN ADRENAL GLAND.

COMMENT

The renal cell carcinoma invades into the renal vein. The perinephric adipose tissue and renal sinus adipose tissue are free of tumor. Tumor is also present within vascular-lymphatic spaces within the renal sinus adipose tissue.

GROSS DESCRIPTION

(A) RIGHT KIDNEY, VACCINE PROTOCOL - A radical nephrectomy specimen with surrounding perinephric adipose tissue (16.0 x 10.0 x 5.0 cm overall), including the kidney (11.0 x 5.5 x 4.2 cm) and attached length of ureter (4.7 cm x 0.4 cm). No adrenal gland is present.

A tan-yellow circumscribed tumor (4.0 x 3.5 x 3.0 cm) is located in the mid-pole of the kidney. The tumor is approximately 0.3 cm from Gerota's fascia. The tumor appears confined to the renal parenchyma. Areas of renal sinus involvement are grossly noted. Tumor is present within the renal vein, approximately 1 cm from the margin of resection.

The remaining uninvolved kidney is red-brown and unremarkable. Portion of the tumor is submitted for the vaccine protocol. A portion of tumor is sequestered for potential electron microscopy.

INK CODE: Black = Gerota's fascia.

SECTION CODE: A1, renal arteries, vein, and ureter margins, en face; A2, tumor within renal vein; A3-A6, tumor and renal sinus; A7, tumor and Gerota's fascia; A8-A10, tumor and normal; A11-A12, representative sections of tumor; A13, representative sections of normal. [REDACTED]

(B) LEFT ADRENAL GLAND FOR VACCINE PROTOCOL - An adrenal gland (7.0 x 3.5 x 3.5 cm) largely replaced by a yellow-tan lobulated tumor (5.0 x 3.5 x 3.5 cm). Focally, within the tumor are areas of gray mucoid material. Focal areas of the specimen show chocolate brown tissue suggestive of normal adrenal. Portions of the tumor are submitted for the vaccine protocol.

SECTION CODE: B1, tumor and normal; B2-B4, representative sections of tumor. [REDACTED]

CLINICAL HISTORY

Right renal mass. Left adrenal.

SNOMED CODES

Source: NCI Genomic Data Commons file cc400428-7915-4ee7-a938-169e3da73f83 (TCGA-CJ-4887.61B37761-0FC3-4AB8-BB5A-9442040DCC63.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).